TARGET case TARGET-50-PAKNTW — High-Risk Wilms Tumor (TARGET-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7fd45d0f-75b9-50b0-a232-a725663cf2ae

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 13 years; Vital status: Alive.

Diagnoses (1)
1. Wilms tumor: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 13.1 years (4,779 days); Year of diagnosis: 2001; Days to last follow up: 290 days; Pediatric kidney staging: Nephrectomy specimen with tumor that is present at the surgical margin of resection or within regional lymph nodes, no distant metastasis; Wilms tumor histologic subtype: Favorable.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (1 entry)
- Days to follow up: 290 days; Event-free: no event (relapse, second malignancy or death) recorded through day 290; Year of follow up: 2003.

Biospecimens (3 samples)
- Samples TARGET-50-PAKNTW-01A, TARGET-50-PAKNTW-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-50-PAKNTW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 290
- Stage: III
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: FHWT

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAKNTW-01A:
- Histological Subtype: relapse Wilms
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: Yes
- % Tumor Nuclei: Top: 95
- % Non tumor Nuclei: Top: 5
- % Cellular Tumor: Top: 90
- % Normal: Top: 0
- % Stroma: Top: 10
- % Necrosis: Top: 0
- % Tumor Nuclei: Bottom: 90
- % Non tumor Nuclei: Bottom: 10
- % Cellular Tumor: Bottom: 85
- % Normal: Bottom: 0
- % Stroma: Bottom: 15
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: Pass

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAKNTW-01A-02:
- Histological Subtype: relapse Wilms
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: yes
- % Tumor Nuclei: Top: 99
- % Non tumor Nuclei: Top: 1
- % Cellular Tumor: Top: 100
- % Normal: Top: 0
- % Stroma: Top: 0
- % Necrosis: Top: 0
- % Tumor Nuclei: Bottom: 99
- % Non tumor Nuclei: Bottom: 1
- % Cellular Tumor: Bottom: 100
- % Normal: Bottom: 0
- % Stroma: Bottom: 0
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: pass
